Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81F, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81F-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology review reported by the

Pathoanatomical review

Date:

Date report:

Material: left adrenal

Macroscopic, there is a 7.4 cm yellowish tumor which is sharply separated from the surrounding tissue.

Histologically, the tumor is composed with zellballen, partly also with a trabecular architecture. Nuclei are enlarged and the broad cytoplasm is weakly eosinophil. Focally, cells are pigmented. Fokal areas of bleeding are present. No enhanced numbers of mitosis, no atypic mitotic figures, no necrotic areas. The capsule is infiltrated, without destruction. Additionally, in central aswell as in peripheral parts of the tumor, invasion into vessels is noted. The surrounding soft tissue is free of tumor invasion.

There is marked staining for synaptophysin and less intense staining for chromogranin. Single sustentacular cells stain weakly positive for S100. The proliferationindex (Ki67) is less than 5%.

Final diagnosis: pheochromocytoma

Translated by:

ICD-O-3
Pheochromocytoma NOS 8700/0
Site: Adrenal gland NOS C74.9
JW 10/17/13

Source: NCI Genomic Data Commons file 16ea5f85-7f85-4740-a691-b225d532f760 (TCGA-WB-A81F.5FDAC35B-6228-4D31-99D5-30F732EAAE78.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).